Gene-level copy-number profile of tumor specimen ALCH-AESI-TTP1-A from ALCHEMIST case ALCH-AESI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.1 years (21,203 days).
Specimen ALCH-AESI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 717faff7-a6d9-4e8c-b4e7-ce6885f37959.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AESI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,764 have no estimate.
https://portal.gdc.cancer.gov/files/a103f814-547a-4a9c-990c-083de3fc392c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 10,437; copy number 2: 46,605; copy number 3: 1,600; copy number 4: 113; copy number 5: 4; copy number 6: 5; copy number 9: 2; copy number 12: 3; copy number 14: 1; copy number 16: 2; copy number 17: 1; copy number 31: 3.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:44,775,251–44,788,170, 8 genes (within-gene range 0–2): RPS8, SNORD55, SNORD46, SNORD38A, SNORD38B, SNORD38B, RPS15AP11, BEST4.
- chr1:92,473,043–92,486,925, 1 gene: GFI1.
- chr1:243,049,782–243,101,744, 4 genes (within-gene range 0–2): CICP21, AL606534.4, LINC01347, RNU6-747P.
- chr3:138,889,255–138,889,957, 1 gene: ATP5MC1P3.
- chr8:37,784,191–37,844,896, 1 gene (within-gene range 0–1): ADGRA2.
- chr9:6,645,956–6,670,635, 4 genes (within-gene range 0–2): AL162411.1, RN7SL123P, RPS3AP54, RNF2P1.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–1): CRB2.
- chr10:13,308,145–13,308,447, 1 gene: RBISP1.
- chr10:15,015,370–15,073,853, 2 genes: DCLRE1CP1, OLAH.
- chr10:133,278,630–133,312,337, 2 genes (within-gene range 0–2): TUBGCP2, AL360181.2.
- chr12:12,915,829–12,915,918, 1 gene (within-gene range 0–2): MIR614.
- chr12:131,828,393–131,851,783, 1 gene: MMP17.
- chr14:74,303,069–74,360,008, 2 genes (within-gene range 0–1): VRTN, SUB1P2.
- chr15:41,517,176–41,544,269, 1 gene: RPAP1.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:74,307,210–74,309,790, 1 gene (within-gene range 0–2): AC103809.1.
- chr17:81,637,171–81,673,904, 4 genes (within-gene range 0–2): TSPAN10, PDE6G, OXLD1, CCDC137.
- chr19:4,502,180–4,518,465, 1 gene (within-gene range 0–1): PLIN4.
- chr19:38,289,151–38,317,273, 5 genes (within-gene range 0–2): AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33.
- chr22:18,605,355–18,611,919, 3 genes: AC023490.1, RN7SKP131, RIMBP3.
- chr22:41,909,554–41,914,667, 1 gene: SHISA8.
- chr22:50,445,000–50,475,035, 1 gene (within-gene range 0–2): SBF1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 6 (within-gene range 4–6): TTC34, AC242022.2, AC242022.1.
- chr9:65,189,995–65,230,861, 3 genes, copy number 6–17: BMS1P12, AL512605.1, AL512605.2.
- chr9:65,287,914–65,323,015, 1 gene, copy number 14: CBWD4P.
- chr20:62,877,738–62,969,585, 4 genes, copy number 5: DIDO1, AL117379.1, GID8, SLC17A9.
- chr21:44,217,014–44,244,993, 3 genes, copy number 31: ICOSLG, AP001059.2, AP001059.1.
- chr22:18,524,620–18,530,573, 3 genes, copy number 12: Metazoa_SRP, AC023490.3, TMEM191B.
- chr22:18,615,581–18,653,617, 4 genes, copy number 9–16: Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 7,649. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
